Somatic mutation profile of tumor specimen 0DJ4C5 from CCDI case PBBWPP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.3 years (5,964 days).
Specimen 0DJ4C5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a245c0a0-6045-411e-89fa-9e5f5759bfee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ4CC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c25ba30b-e231-406d-b62c-1ef3d32f11bb

The open-access MAF lists 51 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, 3'UTR 5, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KPNA7 | c.106C>T p.R36* | Nonsense Mutation (SNP) | VAF 127/854 reads (15%) | catalogued as rs760378316, COSV59400660; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ANKRD61 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 155/1007 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs565373057; called by muse, mutect2, varscan2
- AOC3 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 55/499 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1211492816, COSV53828526; called by muse, mutect2, varscan2
- BAIAP3 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 88/460 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs373118062; called by muse, varscan2
- BIVM-ERCC5 | c.4547A>G p.N1516S | Missense Mutation (SNP) | VAF 157/700 reads (22%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.955); catalogued as rs754375913; called by muse, mutect2, varscan2
- DENND4B | c.2449C>T p.R817W | Missense Mutation (SNP) | VAF 148/794 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1237881352; called by muse, mutect2, varscan2
- FCHO2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs369958358, COSV59274642; called by muse, mutect2, varscan2
- ICE1 | c.6067C>A p.P2023T | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99663811; called by muse, mutect2
- IFT57 | c.1181T>C p.I394T | Missense Mutation (SNP) | VAF 174/523 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.21); catalogued as rs1380665285; called by muse, mutect2, varscan2
- IQSEC3 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 128/740 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs782595467; called by muse, mutect2, varscan2
- KIF23 | c.2795G>T p.R932M (on ENST00000260363; = p.R828M on NM_004856.7) | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99532104; called by muse, mutect2, varscan2
- NLRP5 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs565850613, COSV101173707; called by muse, mutect2, varscan2
- OR4N5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs139342567; called by muse, mutect2, varscan2
- PFKP | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1416468984; called by muse, mutect2, varscan2
- POLE2 | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1566528751; called by muse, mutect2, varscan2
- SHMT2 | c.1273C>T p.R425W | Missense Mutation (SNP) | VAF 149/571 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754743336; called by muse, mutect2, varscan2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 134/504 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by muse, mutect2, varscan2
- TENM2 | c.2453G>A p.G818E (on ENST00000518659 / NM_001122679.2; = p.G586E on NM_001080428.3) | Missense Mutation (SNP) | VAF 123/593 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101319476; called by muse, mutect2, varscan2
- USP44 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 135/443 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs375010013; called by muse, mutect2, varscan2
- ZDBF2 | c.6959C>A p.S2320Y | Missense Mutation (SNP) | VAF 63/474 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV65624558; called by muse, mutect2, varscan2
- AOC1 | c.105C>G p.D35E | Missense Mutation (SNP) | VAF 134/1100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- C17orf113 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 123/1028 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- DEFA5 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 54/273 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ITPRID1 | c.3097T>C p.F1033L | Missense Mutation (SNP) | VAF 62/458 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); called by mutect2, varscan2
- NPR3 | c.1477C>G p.L493V (on ENST00000265074 / NM_001364458.2; = p.L492V on NM_000908.4) | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR5H14 | c.11A>G p.E4G | Missense Mutation (SNP) | VAF 109/496 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR7C2 | c.828G>C p.M276I | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PLEKHA7 | c.1514T>C p.L505P | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PPP1R27 | c.305A>T p.H102L | Missense Mutation (SNP) | VAF 159/874 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAI1 | c.98C>G p.P33R | Missense Mutation (SNP) | VAF 144/467 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- RPTN | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 116/595 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- SLC6A18 | c.954C>G p.D318E | Missense Mutation (SNP) | VAF 79/382 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SPTA1 | c.5353G>C p.V1785L | Missense Mutation (SNP) | VAF 141/943 reads (15%) | SIFT tolerated (0.97); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TMCC2 | c.1285G>T p.A429S | Missense Mutation (SNP) | VAF 21/489 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNNT2 | c.771G>T p.K257N (on ENST00000236918; = p.K254N on NM_000364.4) | Missense Mutation (SNP) | VAF 66/666 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DLC1 | c.2649G>A p.P883= (on ENST00000276297 / NM_001348081.2; = p.P446= on NM_006094.5) | Silent (SNP) | VAF 119/347 reads (34%) | catalogued as rs371200708, COSV52334211, COSV99362099; called by muse, mutect2, varscan2
- FSD1 | c.612G>A p.R204= | Silent (SNP) | VAF 84/694 reads (12%) | catalogued as COSV55696032; called by muse, mutect2, varscan2
- INSYN2A | c.1195C>A p.R399= | Silent (SNP) | VAF 59/299 reads (20%) | catalogued as rs749601173; called by muse, mutect2, varscan2
- LATS2 | c.318A>G p.E106= | Silent (SNP) | VAF 85/383 reads (22%) | called by muse, mutect2, varscan2
- LRRN3 | c.348T>C p.P116= | Silent (SNP) | VAF 31/902 reads (3%) | called by muse, mutect2
- MGAT4B | c.634C>T p.L212= | Silent (SNP) | VAF 203/812 reads (25%) | catalogued as rs758073876; called by muse, mutect2, varscan2
- PRDM16 | c.3426C>T p.T1142= | Silent (SNP) | VAF 95/583 reads (16%) | catalogued as rs372593261; called by muse, mutect2, varscan2
- STXBP4 | c.1293T>C p.L431= | Silent (SNP) | VAF 107/881 reads (12%) | called by muse, mutect2, varscan2
- VSTM4 | c.90G>A p.P30= | Silent (SNP) | VAF 123/592 reads (21%) | catalogued as rs1320699071; called by muse, mutect2, varscan2
- ADAMTSL2 | c.*42C>T | 3'UTR (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- BACH1 | c.*52G>A | 3'UTR (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- C16orf89 | c.*234G>T | 3'UTR (SNP) | VAF 17/451 reads (4%) | called by muse, mutect2
- DAO | c.*29C>A | 3'UTR (SNP) | VAF 80/515 reads (16%) | called by muse, mutect2, varscan2
- LAMC2 | c.3070-77dup | Intron (INS) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- SLC25A40 | c.*74C>A | 3'UTR (SNP) | VAF 41/255 reads (16%) | called by mutect2, varscan2
- ZNF383 | c.-38G>A | 5'UTR (SNP) | VAF 57/450 reads (13%) | catalogued as rs1373731981; called by muse, mutect2, varscan2
